PECGS case C083-000007 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/bea9cabe-15d7-48fa-81fe-e3ab8aff75cd

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 48 years; Year of birth: 1973; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 48.0 years (17,532 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Other clinical attributes
- BMI: 29.29; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000007_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000007_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
